Somatic mutation profile of cancer-model specimen HCM-WCMC-0673-C56-85B (3D Organoid, passage 5; aliquot HCM-WCMC-0673-C56-85B-01D-A85C-36), derived from the primary tumor of HCMI case HCM-WCMC-0673-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Ovary; AJCC pathologic stage: Stage IIIA2; FIGO stage: Stage III; Age at diagnosis: 32.9 years (12,015 days).
Specimen HCM-WCMC-0673-C56-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d966aed-def2-451b-8b4c-f37ef33a0fb8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0673-C56-10A (Blood Derived Normal), aliquot HCM-WCMC-0673-C56-10A-01D-A85C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/085f1705-70b1-4b05-baa1-b450ec88fedb

The open-access MAF lists 21 somatic variants for this specimen: 18 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Nonsense Mutation 2, Silent 2, Frame Shift Del 2, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 154/318 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- SMAD4 | c.1157G>A p.G386D | Missense Mutation (SNP) | VAF 142/142 reads (100%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs121912580, CM021284, COSV61684421, COSV61688134, COSV61692671; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.869del p.R290Pfs*55 | Frame Shift Del (DEL) | VAF 327/456 reads (72%) | hotspot (GDC flag); catalogued as CM065493, CM993905, COSV52683585, COSV53296796; called by mutect2, pindel, varscan2
- AIFM2 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 157/384 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs750119679, COSV100325838; called by muse, mutect2, varscan2
- METTL8 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 162/318 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs754629409; called by muse, varscan2
- NLGN4X | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 261/810 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs758529208, COSV52003690; called by muse, mutect2, varscan2
- ULK3 | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 249/504 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1018512142; called by muse, mutect2, varscan2
- ABCC2 | c.3634G>A p.E1212K | Missense Mutation (SNP) | VAF 144/332 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ATP1A2 | c.754G>T p.A252S | Missense Mutation (SNP) | VAF 140/317 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- CDKN2A | c.263_264del p.E88Gfs*31 | Frame Shift Del (DEL) | VAF 428/694 reads (62%) | called by pindel, varscan2
- COL4A6 | c.272A>T p.K91I | Missense Mutation (SNP) | VAF 12/296 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2
- CTSG | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 139/504 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM81B | c.1214A>G p.E405G | Missense Mutation (SNP) | VAF 10/276 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- KMT2D | c.8104C>T p.Q2702* | Nonsense Mutation (SNP) | VAF 21/742 reads (3%) | called by muse, mutect2
- LARS1 | c.1284+1G>T p.X428_splice (on ENST00000394434 / NM_020117.11; = p.X401_splice on NM_016460.3) | Splice Site (SNP) | VAF 92/241 reads (38%) | called by muse, mutect2, varscan2
- OXSR1 | c.857T>G p.L286* | Nonsense Mutation (SNP) | VAF 134/377 reads (36%) | called by muse, mutect2, varscan2
- PDPR | c.1988G>A p.G663E | Missense Mutation (SNP) | VAF 172/388 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2
- PRSS54 | c.1030G>C p.G344R | Missense Mutation (SNP) | VAF 222/511 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GPRC5B | c.498G>A p.A166= | Silent (SNP) | VAF 234/737 reads (32%) | catalogued as rs1288522295; called by muse, varscan2
- SLC26A3 | c.138C>T p.S46= | Silent (SNP) | VAF 124/253 reads (49%) | catalogued as rs750358656; called by muse, mutect2, varscan2
- FUT9 | c.*7911A>G | 3'UTR (SNP) | VAF 196/386 reads (51%) | catalogued as COSV100133553; called by muse, mutect2, varscan2
